Surgical pathology report (de-identified scan), TCGA case TCGA-DV-5567, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-DV-5567-01A (Primary Tumor).

[page 1 of 5]
DIAGNOSIS:

1. Kidney, right, tumor #1 (excision): Renal cell carcinoma, clear cell type, Fuhrman nuclear grade II
2. Kidney, right, tumor #2 (excision): Renal cell carcinoma, clear cell type, Fuhrman nuclear grade II
3. Kidney, right, tumor #3 (excision): Fibrous hyalinized tissue
4. Kidney, right, tumor #4 (excision): Renal cell carcinoma, clear cell type, Fuhrman nuclear grade II
5. Kidney, right, tumor #5 (excision): Renal cell carcinoma, clear cell type, Fuhrman nuclear grade II
6. Kidney, right, tumor #6 (excision): Clusters of tumor cells in fibrous tissue
7. Kidney, right, tumor #7 (excision): Renal cysts
8. Kidney, right, tumor #8 (excision): Renal cell carcinoma, clear cell type, Fuhrman nuclear grade II
9. Kidney, right, tumor #9 (excision): Atypical renal cyst
10. Kidney, right, tumor #10 (excision): Atypical renal cyst
11. Kidney, right, tumor #11 (excision): Atypical renal cyst
12. Kidney, right, tumor #12 (excision): Atypical renal cyst
13. Kidney, right, tumor #13 (excision): Atypical renal cyst
14. Kidney, right, tumor #14 (excision): Renal cell carcinoma, clear cell type, Fuhrman nuclear grade II

Patient Identification

[page 2 of 5]
-
15. Kidney, right, tumor #15 (excision): Renal cell carcinoma, clear cell type, Fuhrman nuclear grade II
16. Kidney, right, tumor #16 (excision): Renal cell carcinoma, clear cell type, Fuhrman nuclear grade II
17. Kidney, right, tumor #17 (excision): Renal cell carcinoma, clear cell type, Fuhrman nuclear grade II
18. Kidney, right, tumor #18 (excision): Renal cell carcinoma, clear cell type, Fuhrman nuclear grade II
19. Kidney, right, tumor #19 (excision): Atypical renal cyst
20. Rib, right, 11th, (resection): Gross examination only

NOTE:

CLINICAL INFORMATION: Allocate Order to [REDACTED] Brief Clinical History: Patient with VHL, Multiple renal tumors - for partial nephrectomy Specimen

PROCEDURE:

SPECIMENS SUBMITTED: 1. TUMOR, # 1

2. TUMOR, # 2
3. TUMOR, # 3
4. TUMOR, # 4
5. TUMOR, # 5
6. TUMOR, # 6
7. TUMOR, # 7
8. TUMOR, # 8
9. TUMOR, # 9
10. TUMOR, # 10
11. TUMOR
12. TUMOR, # 12
13. TUMOR, # 13
14. TUMOR, # 14
15. TUMOR, # 15
16. TUMOR, # 16
17. TUMOR, # 17
18. TUMOR
19. TUMOR
20. RIB, Eleventh right

Patient Identification

[page 3 of 5]
GROSS DESCRIPTION: Received are 20 containers labeled with the patient's name, medical record number, and further described as follows:

1. "Tumor #1" is a yellow/tan piece of tissue measuring 1.5 x 1.1 x 1.0 cm. 90% is procured for Research. The specimen is received in Surgical Pathology and is consistent with the above description. The entire specimen is placed in a white cassette labeled [REDACTED] for permanent processing.
2. "Tumor #2" is a yellow/tan piece of tissue measuring 1.6 x 1.0 x 0.9 cm. 60% is procured for Research. In Surgical Pathology, the specimen is received and is consistent with the above description. The entire specimen is placed in white cassette labeled [REDACTED] for permanent processing.
3. "Tumor #3" is a yellow/tan piece of tissue measuring 0.6 x 0.5 x 0.2 cm. 80% of the specimen is procured for Research. In Surgical Pathology, the specimen is received and is consistent with the above description. The entire specimen is placed in a white cassette labeled [REDACTED] for permanent processing.
4. "Tumor #4" is a yellow/tan piece of tissue measuring 1.3 x 1.2 x 1.0 cm. 85% of the specimen is procured for Research. The specimen is received in Surgical Pathology and is consistent with the above description. The entire specimen is placed in a white cassette labeled [REDACTED] for permanent processing.
5. "Tumor #5" is a yellow/tan piece of tissue measuring 0.8 x 0.6 x 0.5 cm. 80% is procured for Research. The specimen is received in Surgical Pathology and is consistent with the above description. The entire specimen is placed in a white cassette labeled [REDACTED] for permanent processing.
6. "Tumor #6" is a yellow/tan piece of tissue measuring 0.5 x 0.4 x 0.2 cm. None of the specimen is procured for Research. The specimen is received in Surgical Pathology and is consistent with the above description. The entire specimen is submitted in a white cassette labeled [REDACTED] for permanent processing.
7. "Tumor #7" is a yellow/tan piece of tissue measuring 0.7 x 0.6 x 0.5 cm. None of this tissue is procured for Research. In Surgical Pathology, the specimen is received and is consistent with the above description. The entire specimen is submitted in a white cassette labeled [REDACTED] for permanent processing.
8. "Tumor #8" is a yellow/tan piece of tissue measuring 0.8 x 0.7 x 0.6 cm. 80% is procured for Research. In Surgical Pathology, the specimen is received and is consistent with the above description. The entire specimen is placed in a white cassette labeled [REDACTED] for permanent processing.
9. "Tumor #9" is a yellow/tan piece of tissue measuring 1.0 x 1.0 x 1.0 cm. None is procured for Research. In Surgical Pathology, the specimen is received and is consistent with the above description. The entire specimen is placed in a white cassette labeled [REDACTED] #9 for permanent processing.

Patient Identification

[page 4 of 5]
10. "Tumor #10" is a yellow/tan piece of tissue measuring 0.2 x 0.2 x 0.2 cm and is consistent with a cyst wall. None is procured for Research. In Surgical Pathology, the specimen is received and is consistent with the above description. The entire specimen is placed in a white cassette labeled #10 for permanent processing.

11. "Tumor #11" is a yellow/tan piece of tissue measuring 2.0 x 1.6 x 1.3 cm and is consistent with a cyst wall. None of this is procured for Research. The specimen is received in Surgical Pathology and is consistent with the above description. The entire sample is placed in a white cassette labeled #11 for permanent processing.

12. "Tumor #12" is a yellow/tan piece of tissue measuring 2.0 x 2.0 x 1.5 cm and is consistent with a cyst wall. None of this is procured for Research. The specimen is received in Surgical Pathology and is consistent with the above description. The entire specimen is submitted in a white cassette labeled #12 for permanent processing.

13. "Tumor #13" is a white/tan piece of tissue measuring 1.2 x 1.1 x 0.8 cm and is consistent with a cyst wall. None of this is procured for Research. The specimen is received in Surgical Pathology and is consistent with the above description. The entire specimen is submitted in a white cassette labeled #13 for permanent processing.

14. "Tumor #14" is a yellow/tan piece of tissue measuring 1.1 x 1.0 x 0.8 cm. None of this tissue is procured for Research. The specimen is received in Surgical Pathology and is consistent with the above description. The entire specimen is submitted in a white cassette labeled #14 for permanent processing.

15. "Tumor #15" is a yellow/tan piece of tissue measuring 2.2 x 1.7 x 1.5 cm. 50% is procured for Research. The specimen is received in Surgical Pathology and is consistent with the above description. The entire specimen is submitted in a white cassette labeled #15 for permanent processing.

16. "Tumor #16" is a yellow/tan piece of tissue measuring 2.8 x 2.5 x 2.2 cm. 60% is procured for Research. The specimen is received in Surgical Pathology and is consistent with the above description. The entire specimen is submitted in a white cassette labeled #16 for permanent processing.

17. "Tumor #17" is a yellow/tan piece of tissue measuring 2.4 x 1.8 x 1.5 cm. 70% is procured for Research. The specimen is received in Surgical Pathology and is consistent with the above description. The entire specimen is submitted in a white cassette labeled #17 for permanent processing.

18. "Tumor #18" is a yellow/tan piece of tissue measuring 2.7 x 2.3 x 1.9 cm. 70% is procured for Research. In Surgical Pathology, the specimen is received and is consistent with the above description. The entire specimen is submitted in a white cassette labeled #18 for permanent processing.

Patient Identification

[page 5 of 5]
19. "Tumor #19" is a yellow/tan piece of tissue measuring 0.8 x 0.8 x 0.5 cm. None of this tissue is procured for Research. The specimen is received in Surgical Pathology and is consistent with the above description. The entire specimen is submitted in a white cassette labeled "19 for permanent processing.

20. "11th right rib" are three white tissue fragments measuring 4 x 1 x 0.8 cm in aggregate. No tumor or lesions are seen.

All of the procurements for research were performed by Dr.

No consultants

Patient Identification

Source: NCI Genomic Data Commons file 53a434aa-fa79-4b04-94aa-dd8affe6155a (TCGA-DV-5567.53E81829-540C-4456-A0AD-DDB6B0AAB7C0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).